Somatic mutation profile of tumor specimen TCGA-BR-A4J1-01A (aliquot TCGA-BR-A4J1-01A-11D-A25D-08) from TCGA case TCGA-BR-A4J1, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.7 years (23,266 days).
Specimen TCGA-BR-A4J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a41f6f9-f108-4f86-a425-108a848c2016.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4J1-10A (Blood Derived Normal), aliquot TCGA-BR-A4J1-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/806aa7cd-fb27-4dee-9517-4788b227fabe

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Nonsense Mutation 6, Splice Region 2, Splice Site 2, Frame Shift Del 1, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.3105C>T p.V1035= | Splice Region (SNP) | VAF 6/54 reads (11%) | catalogued as COSV53241163; called by muse, mutect2, varscan2
- ADGRV1 | c.8789C>T p.T2930I | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67983407; called by muse, mutect2, varscan2
- AKAP3 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV57415791; called by muse, mutect2, varscan2
- ARHGAP24 | c.1834G>C p.D612H (on ENST00000395184 / NM_001025616.3; = p.D519H on NM_031305.3) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV51988431; called by muse, mutect2, varscan2
- ATRNL1 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61802538; called by muse, mutect2, varscan2
- CCDC71 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs552840556, COSV58910056; called by muse, mutect2, varscan2
- CELA2A | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62747420; called by muse, mutect2
- CEP290 | c.4681C>T p.R1561C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as rs763605289, COSV58350861; called by muse, mutect2, varscan2
- CNOT3 | c.168+1G>C p.X56_splice | Splice Site (SNP) | VAF 16/82 reads (20%) | catalogued as COSV55362302; called by muse, mutect2, varscan2
- CUX2 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs1052340489, COSV55629725; called by muse, mutect2, varscan2
- DHX8 | c.1885A>G p.R629G | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52252825; called by muse, mutect2, varscan2
- DLGAP1 | c.1965+1G>C p.X655_splice | Splice Site (SNP) | VAF 10/160 reads (6%) | catalogued as COSV59798282; called by muse, mutect2
- DOCK11 | c.4994C>T p.A1665V | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs146074785, COSV52237325; called by muse, mutect2, varscan2
- DSCAM | c.5510G>A p.C1837Y | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68025151; called by muse, mutect2, varscan2
- EFCAB12 | c.275C>A p.A92D | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.277); catalogued as COSV100394781; called by muse, mutect2, varscan2
- EPB41L4A | c.36C>A p.Y12* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV54867599; called by muse, mutect2, varscan2
- FBXW11 | c.1520G>T p.S507I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51608448; called by muse, mutect2, varscan2
- FILIP1L | c.1981C>T p.R661* (on ENST00000354552 / NM_182909.3; = p.R421* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/112 reads (35%) | catalogued as rs771815841, COSV58767876; called by muse, mutect2, varscan2
- IGSF10 | c.3956C>G p.P1319R | Missense Mutation (SNP) | VAF 206/267 reads (77%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56784060, COSV56785947; called by muse, mutect2, varscan2
- IGSF9 | c.1420C>T p.R474* (on ENST00000368094 / NM_001135050.2; = p.R458* on NM_020789.4) | Nonsense Mutation (SNP) | VAF 49/66 reads (74%) | catalogued as rs569197292, COSV63639710; called by muse, mutect2, varscan2
- JCAD | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV64759120; called by muse, mutect2, varscan2
- KCNQ5 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs777062053, COSV59649876; called by muse, mutect2, varscan2
- KCNU1 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV67754940; called by muse, mutect2, varscan2
- KLHL13 | c.1870G>T p.E624* | Nonsense Mutation (SNP) | VAF 48/63 reads (76%) | catalogued as COSV53246755; called by muse, mutect2, varscan2
- KRT8 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV53176933; called by muse, mutect2, varscan2
- MAP7D1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs780310575, COSV60214922; called by muse, mutect2, varscan2
- MIS18BP1 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778996061, COSV60370269; called by muse, mutect2, varscan2
- MORN1 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100087988; called by muse, mutect2, varscan2
- MROH5 | c.1310A>C p.E437A | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV71301151; called by muse, mutect2, varscan2
- MTG2 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as rs144895756; called by muse, mutect2, varscan2
- NEO1 | c.1426T>C p.F476L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV56070113; called by muse, mutect2, varscan2
- NLGN4X | c.401C>G p.T134S | Missense Mutation (SNP) | VAF 63/80 reads (79%) | SIFT tolerated (0.84); PolyPhen benign (0.035); catalogued as COSV52013963; called by muse, mutect2, varscan2
- OMA1 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.415); catalogued as COSV62255062; called by muse, mutect2, varscan2
- OR6M1 | c.442G>C p.V148L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.068); catalogued as COSV58433319; called by muse, mutect2, varscan2
- PAPOLB | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs772459712, COSV68200322; called by muse, mutect2, varscan2
- PARD3B | c.3355A>G p.M1119V (on ENST00000406610 / NM_001302769.2; = p.M1050V on NM_057177.7) | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62509007; called by muse, mutect2, varscan2
- PDE3A | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs772459607, COSV62971319; called by muse, mutect2, varscan2
- PHF14 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV68855020; called by muse, mutect2, varscan2
- PLAAT1 | c.761C>A p.A254D (on ENST00000650797; = p.A149D on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV53230991, COSV53231305; called by muse, mutect2, varscan2
- PSG7 | c.722A>T p.K241M | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV68444862; called by muse, mutect2, varscan2
- SLIT1 | c.2748T>C p.G916= | Splice Region (SNP) | VAF 32/77 reads (42%) | catalogued as COSV56587366; called by muse, mutect2, varscan2
- SLITRK6 | c.1295T>G p.L432R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as COSV68389920; called by muse, mutect2, varscan2
- TAF6 | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV59841330; called by muse, mutect2, varscan2
- TDRD3 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV52155786; called by muse, mutect2, varscan2
- TFAP2C | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as rs769025070, COSV52371157; called by muse, mutect2, varscan2
- TRIM28 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 132/152 reads (87%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as rs1371107136, COSV53399757; called by muse, mutect2, varscan2
- UHRF1 | c.538G>C p.E180Q (on ENST00000612630 / NM_001290050.1; = p.E193Q on NM_013282.4) | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV53573140, COSV53573972; called by muse, mutect2, varscan2
- UMPS | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs142909683, COSV51736876; called by muse, mutect2, varscan2
- ZNF574 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 94/111 reads (85%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs769438304, COSV55902833; called by muse, mutect2, varscan2
- ZNF638 | c.3591G>C p.E1197D | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV52485475; called by muse, mutect2, varscan2
- ZNF701 | c.995G>T p.G332V (on ENST00000301093; = p.G266V on NM_018260.3) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV56524169; called by muse, mutect2, varscan2
- ARID1A | c.3917_3920del p.Q1306Rfs*174 | Frame Shift Del (DEL) | VAF 61/96 reads (64%) | called by pindel, varscan2
- BCAS1 | c.1227A>T p.V409= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as COSV65085315; called by muse, mutect2
- C11orf49 | c.25C>T p.L9= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV53565103; called by muse, mutect2, varscan2
- CCDC102B | c.861A>G p.R287= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV60139152; called by muse, mutect2, varscan2
- CCNL2 | c.564T>G p.G188= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV68766509; called by muse, mutect2, varscan2
- CDK13 | c.3627A>C p.G1209= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV51698827; called by muse, mutect2, varscan2
- CEP97 | c.669C>T p.I223= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs193228690; called by mutect2, varscan2
- CIT | c.3459G>C p.L1153= | Silent (SNP) | VAF 79/286 reads (28%) | catalogued as COSV55866041; called by muse, mutect2, varscan2
- KIF20A | c.2055C>T p.S685= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV67509696; called by muse, mutect2, varscan2
- MBD5 | c.3183G>A p.P1061= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs752275705, COSV68696630; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRPS15 | c.12C>T p.V4= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV58965502; called by muse, mutect2, varscan2
- NOP9 | c.1071G>A p.Q357= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV51865399; called by muse, mutect2, varscan2
- PCDHGA10 | c.1098G>A p.L366= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV53931053; called by muse, mutect2
- PRKAG3 | c.387C>T p.S129= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV52101493; called by muse, mutect2, varscan2
- RALGAPA2 | c.5451C>T p.N1817= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs778013504, COSV52494709; called by mutect2, varscan2
- SCN4A | c.3204C>A p.A1068= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV71126446; called by muse, mutect2, varscan2
- SIRPB1 | c.900C>A p.T300= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV53538315; called by muse, mutect2, varscan2
- ZNF514 | c.546T>C p.D182= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as COSV54633787; called by muse, mutect2, varscan2
- ILF3 | c.*258del | 3'UTR (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- MIR92A1 | n.68G>T | RNA (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- POLR3D | chr8:22244993 T>C | 5'Flank (SNP) | VAF 45/61 reads (74%) | called by muse, mutect2, varscan2
